Somatic mutation profile of tumor specimen TCGA-44-7669-01A (aliquot TCGA-44-7669-01A-21D-2063-08) from TCGA case TCGA-44-7669, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.9 years (21,893 days).
Specimen TCGA-44-7669-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f32b0dd-1d38-4f67-9ea1-cd5a6fff7895.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-7669-10A (Blood Derived Normal), aliquot TCGA-44-7669-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c1e1479-7719-4391-b758-89526fe6bb26

The open-access MAF lists 495 somatic variants for this specimen: 388 protein-altering or splice-affecting, 97 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 323, Silent 97, Nonsense Mutation 33, Splice Site 13, Frame Shift Del 9, Frame Shift Ins 6, RNA 4, Intron 3, 3'UTR 2, Splice Region 2, Nonstop Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFP | c.543G>A p.W181* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as rs121912685, CM090900, COSV56923780; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKD2 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553925453, CM020955, CM163930, COSV99417179; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1215+1G>T p.X405_splice | Splice Site (SNP) | VAF 29/83 reads (35%) | hotspot (GDC flag); catalogued as CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; called by muse, mutect2, varscan2
- SMAD4 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 29/46 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61685508, COSV61687178; called by muse, mutect2, varscan2
- STK11 | c.250A>T p.K84* | Nonsense Mutation (SNP) | VAF 8/10 reads (80%) | hotspot (GDC flag); catalogued as rs137853076, CM981866, COSV58820372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 38/81 reads (47%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2274G>T p.R758S | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.517); catalogued as COSV99221128; called by muse, mutect2
- ABAT | c.1093T>C p.F365L | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99190925; called by muse, mutect2
- ABCA10 | c.2999A>T p.Y1000F | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.098); catalogued as COSV99288427; called by muse, mutect2, varscan2
- ABCA6 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV99446281; called by muse, mutect2, varscan2
- ABCB1 | c.2741A>T p.Q914L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV99712750; called by muse, mutect2, varscan2
- ABL1 | c.2981G>T p.G994V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV100583823; called by muse, mutect2, varscan2
- ACAN | c.6037A>T p.N2013Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100717771; called by muse, mutect2, varscan2
- ADAM2 | c.274T>C p.C92R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697174; called by muse, mutect2, varscan2
- ADAMTS19 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50764970; called by muse, mutect2, varscan2
- ADGRG4 | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 76/122 reads (62%) | catalogued as COSV99795215; called by muse, mutect2, varscan2
- ADGRL3 | c.2846C>A p.T949K (on ENST00000506720 / NM_001322402.2; = p.T881K on NM_015236.6) | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101547017, COSV72231667; called by muse, mutect2, varscan2
- AGFG2 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV99499281; called by muse, mutect2, varscan2
- ALS2CL | c.8A>C p.N3T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100014942; called by muse, mutect2, varscan2
- ANAPC4 | c.930G>C p.W310C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100193960; called by muse, mutect2, varscan2
- ANKRD30A | c.1175C>G p.P392R (on ENST00000611781; = p.P336R on NM_052997.2) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.804); catalogued as COSV100652614, COSV64606434, COSV64620314; called by muse, mutect2, varscan2
- ANKRD33 | c.365T>A p.L122Q (on ENST00000340970 / NM_001304459.2; = p.L247Q on NM_182608.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100001240; called by muse, mutect2, varscan2
- AOPEP | c.1699G>T p.G567* (on ENST00000375315 / NM_001193329.1; = p.G468* on NM_032823.5) | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV99949445; called by muse, mutect2, varscan2
- AOX1 | c.880C>A p.L294M | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.937); catalogued as COSV101021891; called by muse, mutect2, varscan2
- APBA2 | c.826A>G p.R276G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs772021276, COSV101382117; called by muse, mutect2, varscan2
- ARAP3 | c.2555G>T p.R852L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99499595; called by muse, mutect2, varscan2
- ARHGAP15 | c.71T>A p.V24E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV99709879; called by muse, mutect2, varscan2
- ASPHD2 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV53219249, COSV99313288; called by muse, mutect2, varscan2
- ASPM | c.473A>G p.K158R | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV99660117; called by muse, mutect2
- ATPSCKMT | c.522A>T p.E174D | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV99725816; called by muse, mutect2, varscan2
- ATRNL1 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1554873908, COSV100744942; called by muse, mutect2, varscan2
- BANF1 | c.45G>T p.M15I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100381374; called by muse, mutect2, varscan2
- BMP6 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.04); catalogued as COSV99306744; called by muse, mutect2, varscan2
- BNIPL | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99639451; called by muse, mutect2
- BPIFB2 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV99401340; called by muse, mutect2, varscan2
- BTD | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); catalogued as CM152340, COSV100329526; called by muse, mutect2, varscan2
- C3orf56 | c.101G>T p.W34L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV101228947; called by muse, mutect2, varscan2
- C8A | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV100776478, COSV63486563; called by muse, mutect2, varscan2
- C9 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99661964; called by muse, mutect2, varscan2
- CABIN1 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV99573070; called by muse, mutect2, varscan2
- CAD | c.6428A>G p.Y2143C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99254902; called by muse, mutect2, varscan2
- CAPN15 | c.2306G>A p.S769N | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs755670668, COSV99562391; called by muse, mutect2, varscan2
- CARD18 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs751687288, COSV73233137; called by muse, mutect2, varscan2
- CATSPER3 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99254040; called by muse, mutect2, varscan2
- CAVIN4 | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as COSV100293207; called by muse, mutect2, varscan2
- CCDC114 | c.1189G>T p.G397W | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196621; called by muse, mutect2, varscan2
- CCT6A | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99303388; called by muse, mutect2, varscan2
- CD1B | c.975G>T p.R325S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV100939220, COSV63804618; called by muse, mutect2, varscan2
- CD200R1 | c.238G>T p.G80C (on ENST00000471858 / NM_170780.3; = p.G103C on NM_138806.4) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV99867097; called by muse, mutect2, varscan2
- CD300E | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV100151264; called by muse, mutect2, varscan2
- CD40 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100953824; called by muse, mutect2, varscan2
- CDC42BPA | c.1103C>T p.T368I | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100504663; called by muse, mutect2, varscan2
- CDCA7L | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100651045; called by muse, mutect2, varscan2
- CDH12 | c.2383T>A p.*795Kext*6 | Nonstop Mutation (SNP) | VAF 39/139 reads (28%) | catalogued as COSV101202221; called by muse, mutect2, varscan2
- CDH18 | c.1296C>A p.N432K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99933877; called by muse, mutect2, varscan2
- CDH2 | c.1361C>A p.T454K | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0.112); catalogued as COSV99296519; called by muse, mutect2, varscan2
- CDH22 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100952820; called by muse, mutect2, varscan2
- CDH23 | c.5471G>A p.R1824H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as rs111033491, COSV56469836; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK15 | c.803C>A p.P268H (on ENST00000652192 / NM_001366386.2; = p.P217H on NM_139158.2) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99643016, COSV99643471; called by muse, mutect2, varscan2
- CEBPG | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV99392746; called by muse, mutect2, varscan2
- CEP120 | c.1878G>T p.Q626H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1427214273, COSV100071010; called by muse, mutect2, varscan2
- CFAP65 | c.1130A>T p.E377V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99838302; called by muse, mutect2, varscan2
- CFAP91 | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs565776294, COSV56342427, COSV99847038; called by muse, mutect2, varscan2
- CFHR4 | c.1613A>G p.Y538C (on ENST00000367416 / NM_001201551.2; = p.Y292C on NM_006684.5) | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771020245, COSV99260154; called by muse, mutect2, varscan2
- CHD6 | c.3355G>A p.G1119S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as COSV100498071; called by muse, mutect2
- CHL1 | c.803C>T p.P268L (on ENST00000397491 / NM_001253387.1; = p.P284L on NM_006614.4) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99850862; called by muse, mutect2
- CHRNA2 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774279507, COSV99532135; called by muse, mutect2, varscan2
- CLEC2L | c.357A>T p.R119S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.438); catalogued as COSV101406081; called by muse, mutect2
- CLEC4G | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100183637; called by muse, mutect2, varscan2
- COL21A1 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs780566383, COSV55168403, COSV99778371; called by muse, mutect2, varscan2
- COL24A1 | c.2581G>T p.G861* | Nonsense Mutation (SNP) | VAF 42/117 reads (36%) | catalogued as COSV100993167; called by muse, mutect2, varscan2
- COL5A1 | c.1662G>T p.R554S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100879777; called by muse, mutect2
- COL5A2 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100880180; called by muse, mutect2, varscan2
- COL6A3 | c.3508G>T p.A1170S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.18); catalogued as COSV99797594; called by muse, mutect2, varscan2
- COPA | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV99615331; called by muse, mutect2, varscan2
- CPXM2 | c.1147G>T p.V383L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53861492, COSV53861771; called by muse, varscan2
- CRACD | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV99949056; called by muse, mutect2, varscan2
- CRACD | c.1996G>T p.A666S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51719765, COSV99949057; called by muse, mutect2, varscan2
- CRB1 | c.3190A>G p.S1064G | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100957816; called by muse, mutect2, varscan2
- CRX | c.251A>T p.Q84L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99704427; called by muse, mutect2, varscan2
- CSMD3 | c.9691G>T p.V3231F (on ENST00000297405 / NM_001363185.1; = p.V3062F on NM_052900.3) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99831566; called by muse, mutect2, varscan2
- CSMD3 | c.4751G>C p.C1584S (on ENST00000297405 / NM_001363185.1; = p.C1480S on NM_052900.3) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99831572; called by muse, mutect2, varscan2
- CSTL1 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV99851123; called by muse, mutect2, varscan2
- CTAGE1 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 167/219 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV66943246; called by muse, mutect2, varscan2
- CUTC | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100976154; called by muse, varscan2
- DAZAP1 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99245148; called by muse, mutect2, varscan2
- DCAF4L2 | c.455C>A p.T152N | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV100150738; called by muse, mutect2, varscan2
- DCAF4L2 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60480562, COSV60481042; called by muse, mutect2, varscan2
- DDX1 | c.828G>C p.Q276H | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.571); catalogued as COSV99246163; called by muse, mutect2, varscan2
- DHX58 | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99288180; called by muse, mutect2, varscan2
- DLGAP3 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1340940463, COSV52393413; called by muse, mutect2, varscan2
- DMBX1 | c.944T>A p.L315Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100760740; called by muse, mutect2, varscan2
- DMGDH | c.1291C>A p.R431S | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV54867234, COSV99668797; called by muse, mutect2, varscan2
- DMGDH | c.475A>G p.T159A | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV99668801; called by muse, mutect2, varscan2
- DNAH11 | c.11132G>C p.R3711T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV100178741; called by muse, mutect2, varscan2
- DNAH8 | c.10567C>G p.P3523A | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544511; called by muse, mutect2, varscan2
- DNAH9 | c.1701C>A p.Y567* | Nonsense Mutation (SNP) | VAF 38/65 reads (58%) | catalogued as COSV99305374; called by muse, mutect2, varscan2
- DNAJB11 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99408598; called by muse, mutect2, varscan2
- DOCK10 | c.1528A>T p.K510* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99288968; called by muse, mutect2, varscan2
- DPP6 | c.1048G>A p.E350K (on ENST00000377770 / NM_001364500.2; = p.E288K on NM_001936.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.965); catalogued as rs1282344027, COSV100124730, COSV59608552; called by muse, mutect2, varscan2
- DRD5 | c.545G>T p.R182M | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100431709; called by muse, mutect2, varscan2
- DRD5 | c.546G>T p.R182S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV100431711, COSV58577190; called by muse, mutect2, varscan2
- DSG3 | c.377C>A p.T126K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (1); PolyPhen possibly damaging (0.475); catalogued as COSV57123865; called by muse, mutect2, varscan2
- DUSP26 | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99823401; called by muse, mutect2, varscan2
- DVL1 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101127419, COSV66678930; called by muse, mutect2, varscan2
- DZIP3 | c.2443G>C p.A815P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV100847747; called by muse, mutect2, varscan2
- EFHB | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); catalogued as rs759952652, COSV99859434; called by muse, mutect2, varscan2
- EGLN2 | c.542A>G p.Y181C | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs763604374, COSV100393700; called by muse, mutect2, varscan2
- EHMT1 | c.3433G>T p.D1145Y | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101509629; called by muse, mutect2, varscan2
- EIF3B | c.1996G>T p.V666F | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV100703659; called by muse, mutect2, varscan2
- ELOA2 | c.788C>A p.P263Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as COSV99796362; called by muse, mutect2, varscan2
- EPPK1 | c.6569C>G p.A2190G | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV101599811; called by muse, mutect2
- ETV6 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 71/140 reads (51%) | catalogued as COSV101122495, COSV67150283; called by muse, mutect2, varscan2
- FAF1 | c.1382A>G p.N461S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.088); catalogued as COSV100875478; called by muse, mutect2, varscan2
- FAM135A | c.2196A>T p.L732F (on ENST00000370479 / NM_001351599.1; = p.L519F on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99525619; called by muse, mutect2, varscan2
- FAM13C | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53242843, COSV99513589; called by muse, mutect2, varscan2
- FAM171B | c.1663C>T p.H555Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as COSV100488481; called by muse, mutect2, varscan2
- FAM47A | c.845G>A p.G282D | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.969); catalogued as COSV100649836; called by muse, mutect2, varscan2
- FARSA | c.215G>C p.R72P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV100108781; called by mutect2, varscan2
- FAT1 | c.10367G>T p.G3456V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499287; called by muse, mutect2
- FBXO32 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54891077, COSV99785888; called by muse, mutect2
- FCGR2B | c.519A>C p.K173N | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV99375012; called by muse, mutect2, varscan2
- FCRL3 | c.1593C>A p.N531K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as COSV100943098; called by muse, mutect2, varscan2
- FER1L6 | c.3787A>T p.K1263* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV101205753; called by muse, mutect2, varscan2
- FPGS | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs373011065; called by muse, mutect2
- FRMPD4 | c.1370T>A p.L457Q | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV101041875, COSV101042660; called by muse, mutect2, varscan2
- FSCB | c.2126C>A p.A709E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs767114031, COSV100469191; called by muse, mutect2, varscan2
- FZD1 | c.1700G>T p.R567L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as COSV55312350, COSV99842499; called by muse, mutect2, varscan2
- G6PC | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV99520789; called by muse, mutect2, varscan2
- GABRG2 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.138); catalogued as COSV100729652; called by muse, mutect2, varscan2
- GIMAP8 | c.1911G>T p.Q637H | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.217); catalogued as COSV100217487; called by muse, mutect2, varscan2
- GLIPR1 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV99875638; called by muse, mutect2, varscan2
- GMCL1 | c.1153A>G p.I385V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as COSV99247672; called by muse, mutect2, varscan2
- GNB3 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs370861380, COSV99301146; called by muse, mutect2, varscan2
- GPR149 | c.1724T>A p.V575E | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101078345; called by muse, mutect2, varscan2
- GPR83 | c.713A>T p.Y238F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99703649; called by muse, mutect2, varscan2
- GRIA4 | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.153); catalogued as COSV99230646; called by muse, mutect2, varscan2
- GRIK2 | c.2000C>A p.P667H | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100025161; called by muse, mutect2, varscan2
- GRM6 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV51450248; called by muse, mutect2, varscan2
- H3-4 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.144); catalogued as COSV100797381; called by muse, mutect2, varscan2
- HCST | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV99385572; called by muse, mutect2, varscan2
- HDAC9 | c.124C>A p.R42S | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV101286704; called by muse, mutect2, varscan2
- HHIPL2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100596780; called by muse, mutect2, varscan2
- HIP1 | c.1581+1G>T p.X527_splice | Splice Site (SNP) | VAF 46/190 reads (24%) | catalogued as COSV100417359; called by muse, mutect2, varscan2
- HNRNPF | c.528A>G p.I176M | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as COSV100562954; called by muse, mutect2, varscan2
- HOXB2 | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100344590; called by muse, mutect2, varscan2
- HRG | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs749884290, COSV99214731; called by muse, mutect2, varscan2
- HTR6 | c.296G>T p.C99F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99230077; called by muse, mutect2, varscan2
- IGKV1-12 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1259942444; called by muse, mutect2, varscan2
- IL3RA | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs200321061, COSV58430220; called by muse, mutect2, varscan2
- ILRUN | c.358G>T p.G120* | Nonsense Mutation (SNP) | VAF 91/205 reads (44%) | catalogued as COSV100927212; called by muse, mutect2, varscan2
- IMPG2 | c.627A>T p.E209D | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.321); catalogued as COSV99515315; called by muse, mutect2, varscan2
- INPP5D | c.2821G>T p.A941S (on ENST00000445964 / NM_001017915.3; = p.A940S on NM_005541.5) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.107); catalogued as COSV100856703; called by muse, mutect2, varscan2
- IP6K3 | c.97A>T p.K33* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99539764; called by muse, mutect2, varscan2
- ITIH5 | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV99904389; called by muse, mutect2, varscan2
- ITPRIP | c.651dup p.E218Rfs*138 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | catalogued as rs765312007; called by mutect2, pindel, varscan2
- JCAD | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100948293; called by muse, mutect2, varscan2
- KCNH7 | c.2896G>T p.D966Y | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100147559; called by muse, mutect2, varscan2
- KDM2B | c.1922G>T p.R641L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100997375, COSV65641321; called by muse, mutect2, varscan2
- KDM6A | c.2667A>G p.I889M | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100938083; called by muse, mutect2, varscan2
- KEAP1 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV50263782, COSV50281859; called by muse, mutect2, varscan2
- KIF3A | c.1701T>G p.H567Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as COSV101109313; called by muse, mutect2, varscan2
- KIZ | c.1611A>G p.Q537= | Splice Region (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99852012; called by muse, mutect2, varscan2
- KLHL22 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.526); catalogued as COSV100185950; called by muse, mutect2
- KRTAP11-1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100190593; called by muse, mutect2, varscan2
- KTN1 | c.1450A>T p.T484S | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV101255157; called by muse, mutect2, varscan2
- LAMB1 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99740205, COSV99740510; called by muse, mutect2, varscan2
- LENG1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773775602, COSV99033076; called by muse, mutect2, varscan2
- LGALS4 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs770923216, COSV100313196; called by muse, mutect2, varscan2
- LGR4 | c.2167G>T p.V723F | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as COSV100156523; called by muse, mutect2, varscan2
- LHFPL4 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV99805416; called by muse, mutect2, varscan2
- LONP2 | c.608A>G p.D203G | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753989357, COSV99589066; called by muse, mutect2
- LPA | c.3014C>A p.P1005H | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100306638, COSV60296944; called by muse, mutect2, varscan2
- LRGUK | c.1996A>G p.I666V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53639319; called by muse, mutect2, varscan2
- LRP1B | c.1409-2A>T p.X470_splice | Splice Site (SNP) | VAF 15/50 reads (30%) | catalogued as COSV67272325; called by muse, mutect2, varscan2
- LRRC57 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99535362; called by muse, mutect2, varscan2
- LRRC7 | c.4654G>T p.E1552* (on ENST00000651989 / NM_001370785.2; = p.E1472* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 38/105 reads (36%) | catalogued as COSV50507359, COSV99226034; called by muse, mutect2, varscan2
- LRRFIP2 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1286452590, COSV99212400; called by muse, mutect2, varscan2
- MACO1 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100975115; called by muse, mutect2, varscan2
- MAP4 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100805644, COSV64242335; called by muse, mutect2, varscan2
- MCAM | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99877679; called by muse, mutect2, varscan2
- MCM10 | c.1307G>T p.G436V (on ENST00000484800 / NM_182751.3; = p.G435V on NM_018518.5) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101098065; called by muse, mutect2, varscan2
- MEIS3 | c.840G>C p.W280C | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100520422; called by muse, mutect2, varscan2
- MFAP3L | c.1169C>G p.A390G | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV100852664; called by muse, mutect2, varscan2
- MMEL1 | c.2179T>A p.Y727N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99983635; called by muse, mutect2, varscan2
- MMP8 | c.346A>T p.R116W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99368384; called by muse, mutect2
- MMRN1 | c.2807C>A p.T936K | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99306748, COSV99306961; called by muse, mutect2, varscan2
- MN1 | c.3030G>C p.W1010C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100179785; called by muse, mutect2, varscan2
- MRS2 | c.1189G>T p.G397* | Nonsense Mutation (SNP) | VAF 61/137 reads (45%) | catalogued as COSV99218849; called by muse, mutect2, varscan2
- MUC16 | c.34160C>A p.A11387D | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV101199490; called by muse, mutect2, varscan2
- MUC2 | c.418C>G p.R140G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs541501827; called by muse, mutect2, varscan2
- MYO10 | c.5248C>T p.H1750Y | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV99945179; called by muse, mutect2
- MYO16 | c.1018C>A p.L340M | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.483); catalogued as COSV51796608, COSV99193818; called by muse, mutect2, varscan2
- MYO3A | c.2871G>C p.E957D | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99779308; called by muse, mutect2, varscan2
- MYO7B | c.2156A>T p.K719M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV101268085; called by muse, mutect2, varscan2
- MZT2B | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | catalogued as COSV99919777; called by muse, mutect2, varscan2
- NAV3 | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1251135922, COSV99889560; called by muse, mutect2, varscan2
- NFATC2 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV65355953; called by muse, mutect2, varscan2
- NLRC3 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100072685; called by muse, mutect2, varscan2
- NPAT | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV99585954; called by muse, mutect2, varscan2
- NRXN1 | c.1801C>A p.P601T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.078); catalogued as COSV100454510; called by muse, mutect2, varscan2
- NTNG2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100647394; called by muse, mutect2, varscan2
- NYNRIN | c.3828G>T p.Q1276H | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.936); catalogued as COSV101230572, COSV66842946; called by muse, mutect2, varscan2
- OPLAH | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV101470756; called by muse, mutect2, varscan2
- OR13A1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as rs376781877; called by muse, mutect2, varscan2
- OR2G3 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as rs1428801255, COSV100180466, COSV60681720; called by muse, mutect2, varscan2
- OR2M3 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 14/314 reads (4%) | catalogued as COSV101513423, COSV71758901; called by muse, mutect2
- OR2M5 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs1428817501, COSV63546359; called by muse, mutect2, varscan2
- OR2T1 | c.782C>A p.P261Q | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100822294; called by muse, mutect2, varscan2
- OR4A16 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as rs371963500; called by muse, mutect2, varscan2
- OR4A16 | c.863G>C p.R288T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs763289988, COSV100125164; called by muse, mutect2, varscan2
- OR4C3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149944761, COSV100167734; called by muse, mutect2, varscan2
- OR4C46 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100060615, COSV60218641; called by muse, mutect2, varscan2
- OR4D5 | c.727C>A p.H243N | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100189898; called by muse, mutect2, varscan2
- OR4F21 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as COSV100307510; called by mutect2, varscan2
- OR51D1 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs770923587, COSV100712364; called by muse, mutect2
- OR5K3 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV101051629; called by muse, mutect2, varscan2
- OR6B2 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99401379; called by muse, mutect2, varscan2
- OR6N1 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100625142; called by muse, mutect2, varscan2
- OR6T1 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as COSV100189900; called by muse, varscan2
- OR9Q1 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV100109766; called by muse, mutect2, varscan2
- OSBPL10 | c.977C>G p.S326C | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV101159286; called by muse, mutect2, varscan2
- OSBPL5 | c.2398+1G>T p.X800_splice | Splice Site (SNP) | VAF 30/56 reads (54%) | catalogued as COSV99720299; called by muse, mutect2, varscan2
- OXCT1 | c.1264G>T p.G422* | Nonsense Mutation (SNP) | VAF 30/181 reads (17%) | catalogued as COSV99541996; called by muse, mutect2, varscan2
- P2RX7 | c.1520T>G p.I507S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99947523; called by muse, mutect2, varscan2
- PARD3 | c.1157G>T p.S386I | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100400780; called by muse, mutect2, varscan2
- PASD1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV64856822; called by muse, mutect2, varscan2
- PCDH10 | c.2300G>T p.G767V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as rs918916878, COSV99993385; called by muse, mutect2, varscan2
- PCDH15 | c.5434C>T p.P1812S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.005); catalogued as COSV100219220, COSV57279464; called by muse, mutect2
- PCDH15 | c.3649T>A p.Y1217N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100219223; called by muse, mutect2, varscan2
- PCDH15 | c.2383G>C p.A795P | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100219225, COSV57324926; called by muse, mutect2, varscan2
- PCDH18 | c.3153G>C p.Q1051H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as COSV100787242, COSV61271896; called by muse, mutect2, varscan2
- PCDHA1 | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100974340; called by muse, mutect2, varscan2
- PCDHB10 | c.1330G>T p.V444F | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as rs782384506, COSV99504108; called by muse, mutect2
- PCDHB11 | c.29A>G p.Q10R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53381257, COSV99504109; called by muse, mutect2, varscan2
- PCDHB11 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53383957, COSV99504113; called by muse, mutect2, varscan2
- PCDHB12 | c.115T>G p.L39V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as COSV99507135; called by muse, mutect2, varscan2
- PCDHB2 | c.1336G>T p.V446F | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV99164932; called by muse, mutect2
- PCDHB9 | c.1898G>T p.R633L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.822); catalogued as COSV53375191, COSV53379472; called by muse, mutect2, varscan2
- PCDHGA4 | c.2336C>A p.A779D | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs1161118434, COSV99536003; called by muse, mutect2, varscan2
- PCDHGC3 | c.1522C>A p.R508S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as COSV99339504; called by muse, mutect2, varscan2
- PDE8B | c.449G>T p.W150L | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.312); catalogued as COSV99366618; called by muse, mutect2, varscan2
- PDGFRB | c.1790G>T p.R597L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55803883, COSV99940256; called by muse, mutect2
- PEAK1 | c.5017G>C p.D1673H | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100432864; called by muse, mutect2, varscan2
- PEG3 | c.1319C>A p.T440N | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV55645061; called by muse, mutect2, varscan2
- PER2 | c.2306A>T p.Q769L | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV99611795; called by muse, mutect2, varscan2
- PER2 | c.246C>A p.S82R | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1559335203, COSV99611798; called by muse, mutect2, varscan2
- PGAM4 | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 70/96 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as COSV100430631; called by muse, mutect2, varscan2
- PIWIL1 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV55352178; called by muse, mutect2, varscan2
- PKP2 | c.2401A>G p.N801D | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as CD043197, COSV99297550; called by muse, mutect2, varscan2
- PLAAT1 | c.454G>T p.D152Y (on ENST00000650797; = p.D47Y on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53231761; called by muse, mutect2, varscan2
- PLBD2 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs768853771, COSV55109399, COSV99785275; called by muse, mutect2, varscan2
- PLEC | c.7078C>T p.R2360C (on ENST00000322810 / NM_201380.4; = p.R2250C on NM_000445.5) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs200620255, COSV59655954; ClinVar: uncertain significance; called by mutect2, varscan2
- PLEKHG4B | c.2661+1G>T p.X887_splice (on ENST00000283426; = p.X1243_splice on NM_052909.5) | Splice Site (SNP) | VAF 25/93 reads (27%) | catalogued as COSV99360152; called by muse, mutect2, varscan2
- PLEKHO2 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs376816563; called by muse, mutect2, varscan2
- PLK3 | c.1292T>A p.V431E | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV100221115; called by muse, mutect2, varscan2
- PLPP4 | c.461T>G p.L154R | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100956296; called by muse, mutect2
- POGZ | c.2656A>G p.T886A | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.931); catalogued as COSV99304971; called by muse, mutect2, varscan2
- POM121L12 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs1038488420, COSV101374900, COSV68693408; called by muse, mutect2, varscan2
- POU6F2 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as COSV68868254, COSV68882234; called by muse, mutect2, varscan2
- PRB1 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 101/167 reads (60%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.763); catalogued as COSV99555861; called by muse, mutect2, varscan2
- PRKD1 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765126230, COSV100119966; called by muse, mutect2, varscan2
- PRSS38 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100816462; called by muse, mutect2, varscan2
- PRSS48 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101490169; called by muse, mutect2, varscan2
- PRSS55 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.146); catalogued as rs1343924356, COSV100153733; called by muse, mutect2, varscan2
- PTPN13 | c.4856C>G p.S1619C (on ENST00000411767 / NM_080683.3; = p.S1600C on NM_006264.3) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV100364572; called by muse, mutect2, varscan2
- PTPRD | c.4398C>A p.D1466E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as COSV100644293; called by muse, mutect2, varscan2
- PTPRK | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); catalogued as COSV100949559; called by muse, mutect2, varscan2
- PTPRT | c.2506G>T p.G836W | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV100626660, COSV61982047; called by muse, mutect2, varscan2
- PXDNL | c.2092C>A p.R698S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs958208659, COSV100683116, COSV62493670; called by muse, mutect2, varscan2
- RAB2A | c.422A>G p.H141R | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV99389639; called by muse, mutect2, varscan2
- REXO1 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99402232; called by muse, mutect2, varscan2
- RGS5 | c.183G>T p.W61C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100008980; called by muse, mutect2
- RGS5 | c.182G>T p.W61L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100008982; called by muse, mutect2
- RIMS2 | c.1792G>C p.G598R (on ENST00000666250 / NM_001348490.2; = p.G406R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99166772; called by muse, mutect2, varscan2
- ROBO1 | c.1151G>T p.W384L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71395992; called by muse, mutect2, varscan2
- RSPH14 | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99320647; called by muse, mutect2, varscan2
- RYR2 | c.5725C>A p.L1909M | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100769559; called by muse, mutect2
- RYR2 | c.11870A>T p.K3957M | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100769561; called by muse, mutect2, varscan2
- SEC14L3 | c.661G>T p.G221* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as COSV99307098; called by muse, mutect2, varscan2
- SEC14L3 | c.660G>T p.L220F | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs775652681, COSV53178066, COSV99307103; called by muse, mutect2, varscan2
- SERF2 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | catalogued as COSV99988374; called by muse, mutect2, varscan2
- SERPINE1 | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99776662; called by muse, mutect2, varscan2
- SETD1A | c.4395G>T p.W1465C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52684742; called by muse, mutect2
- SFSWAP | c.389-1G>T p.X130_splice | Splice Site (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99905991; called by muse, mutect2, varscan2
- SGIP1 | c.2186T>C p.I729T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99391190; called by muse, mutect2, varscan2
- SIGLEC7 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.045); catalogued as COSV99978639; called by muse, mutect2, varscan2
- SLC17A3 | c.1037+1G>T p.X346_splice | Splice Site (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100399170; called by muse, mutect2, varscan2
- SLC25A2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs782427876, COSV99508224; called by muse, mutect2
- SLC32A1 | c.163C>A p.R55S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV54147727, COSV99462101; called by muse, mutect2, varscan2
- SLC35F6 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100733644; called by muse, mutect2, varscan2
- SLC4A4 | c.3197-2A>G p.X1066_splice (on ENST00000264485 / NM_001098484.3; = p.X1022_splice on NM_003759.4) | Splice Site (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99139816; called by muse, mutect2, varscan2
- SLC6A14 | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1556694509, COSV100903113, COSV100903228; called by muse, mutect2, varscan2
- SLC9A4 | c.721-2A>G p.X241_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99762931; called by muse, mutect2
- SLCO6A1 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 91/223 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101134238; called by muse, mutect2, varscan2
- SLIT3 | c.3211T>C p.C1071R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100266841; called by muse, mutect2, varscan2
- SORL1 | c.5658G>T p.K1886N | Missense Mutation (SNP) | VAF 118/265 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99493524; called by muse, mutect2, varscan2
- SOX30 | c.880G>C p.V294L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV99398351; called by muse, mutect2, varscan2
- SPANXD | c.289A>G p.K97E | Missense Mutation (SNP) | VAF 69/107 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100982265; called by muse, mutect2, varscan2
- SPG11 | c.6676A>T p.S2226C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99968441; called by muse, mutect2, varscan2
- SPINDOC | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV99588617; called by muse, mutect2, varscan2
- SPTA1 | c.6272C>T p.S2091F | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934746; called by muse, mutect2, varscan2
- ST18 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs764626199, COSV99389219; called by muse, mutect2, varscan2
- SVEP1 | c.7857A>G p.I2619M | Missense Mutation (SNP) | VAF 82/145 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99928833; called by muse, mutect2, varscan2
- SVOP | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 109/261 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV54464324; called by muse, mutect2, varscan2
- SYMPK | c.1834G>A p.V612M | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99841626; called by muse, mutect2, varscan2
- SYT10 | c.941T>A p.L314Q | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99951242; called by muse, mutect2, varscan2
- TAAR9 | c.554C>A p.T185N | Missense Mutation (SNP) | VAF 80/128 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs754573179, COSV101453326; called by muse, mutect2, varscan2
- TAF4B | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV99300085; called by muse, mutect2, varscan2
- TDRD1 | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99314407; called by muse, mutect2, varscan2
- TECTA | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99879523; called by muse, mutect2, varscan2
- TENM3 | c.6220G>T p.V2074L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.208); catalogued as COSV101305041; called by muse, mutect2, varscan2
- TFAP2D | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.049); catalogued as rs938932440, COSV99145858; called by muse, mutect2, varscan2
- TINAG | c.1314G>T p.W438C | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99449154; called by muse, mutect2, varscan2
- TIPRL | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.62); catalogued as COSV100893264; called by muse, mutect2, varscan2
- TM2D3 | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as COSV100254513; called by muse, mutect2, varscan2
- TMEM159 | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV99238621; called by muse, mutect2, varscan2
- TMEM59L | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV99450163; called by muse, mutect2, varscan2
- TMTC1 | c.1419-1G>C p.X473_splice (on ENST00000539277 / NM_001193451.2; = p.X365_splice on NM_175861.3) | Splice Site (SNP) | VAF 13/70 reads (19%) | catalogued as COSV99759358; called by muse, mutect2
- TNPO2 | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV100790332; called by muse, mutect2, varscan2
- TNR | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.952); catalogued as COSV99689051, COSV99690406; called by muse, mutect2, varscan2
- TNXB | c.8144G>T p.G2715V (on ENST00000647633; = p.G2468V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs894516039, COSV100926197; called by muse, mutect2, varscan2
- TPSB2 | c.126G>T p.W42C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV99326639; called by muse, mutect2
- TRIM3 | c.1351C>A p.R451S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100624356; called by muse, mutect2, varscan2
- TRPC6 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534941786, COSV100723557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPM1 | c.875C>A p.A292E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs763506869, COSV99855777; called by muse, mutect2
- TRPS1 | c.1520A>C p.K507T (on ENST00000220888 / NM_001330599.2; = p.K520T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.868); catalogued as COSV99629959; called by muse, varscan2
- TRPV6 | c.2290C>G p.Q764E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100844254; called by muse, mutect2, varscan2
- TTN | c.15952G>A p.E5318K (on ENST00000591111; = p.E4391K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/187 reads (31%) | PolyPhen probably damaging (0.994); catalogued as COSV100606488; called by muse, mutect2, varscan2
- TULP3 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 43/239 reads (18%) | catalogued as COSV101237508; called by muse, mutect2, varscan2
- TYR | c.1427C>G p.S476* | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | catalogued as COSV99633905; called by muse, mutect2, varscan2
- UBN2 | c.3973C>T p.H1325Y | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99943847; called by muse, mutect2, varscan2
- UBQLN3 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100293571; called by muse, mutect2, varscan2
- UGT2A1 | c.976C>T p.L326F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV99684186; called by muse, mutect2, varscan2
- UGT2B7 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs370956653; called by muse, mutect2
- UHRF1BP1L | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99691439; called by muse, mutect2, varscan2
- UNC13C | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV52871082, COSV99036611; called by muse, mutect2, varscan2
- UNC5D | c.2273C>A p.P758H | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54796305, COSV99774363; called by muse, mutect2, varscan2
- UNC79 | c.2434-2A>T p.X812_splice (on ENST00000393151 / NM_001346218.2; = p.X635_splice on NM_020818.5) | Splice Site (SNP) | VAF 25/56 reads (45%) | catalogued as COSV99827258; called by muse, mutect2, varscan2
- UNC79 | c.2434-1G>A p.X812_splice (on ENST00000393151 / NM_001346218.2; = p.X635_splice on NM_020818.5) | Splice Site (SNP) | VAF 24/56 reads (43%) | catalogued as COSV99827261; called by muse, varscan2
- USH2A | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764038972, COSV56332494; called by muse, mutect2, varscan2
- VCAN | c.7634T>C p.I2545T | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV99425465; called by muse, mutect2, varscan2
- VSTM2A | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV100173046; called by muse, mutect2
- VWA3B | c.863C>A p.T288N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101346008; called by muse, mutect2, varscan2
- WDFY3 | c.2246A>T p.E749V | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99883074; called by muse, mutect2, varscan2
- WDR20 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100084981; called by muse, varscan2
- XPO1 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101294197, COSV68946749; called by muse, mutect2, varscan2
- XPO1 | c.1186G>T p.G396* | Nonsense Mutation (SNP) | VAF 63/183 reads (34%) | catalogued as COSV101294198; called by muse, mutect2, varscan2
- ZC3H7B | c.2124G>T p.E708D | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100687276; called by muse, mutect2, varscan2
- ZEB2 | c.2486G>T p.S829I | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV100355754; called by muse, mutect2, varscan2
- ZFC3H1 | c.5749G>T p.V1917F | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV101110481; called by muse, mutect2, varscan2
- ZFP42 | c.883C>G p.H295D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100478794, COSV58817542; called by muse, mutect2, varscan2
- ZNF233 | c.1816T>A p.Y606N | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100492214; called by muse, mutect2, varscan2
- ZNF264 | c.1237T>A p.Y413N | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99567206; called by muse, mutect2, varscan2
- ZNF33A | c.438G>T p.M146I (on ENST00000458705 / NM_006974.3; = p.M147I on NM_006954.2) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100275704; called by muse, mutect2, varscan2
- ZNF345 | c.56A>T p.E19V | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100080166, COSV100080242; called by muse, mutect2, varscan2
- ZNF37A | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100697340; called by muse, mutect2, varscan2
- ZNF516 | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV71586885; called by muse, mutect2
- ZNF569 | c.1552G>T p.G518* | Nonsense Mutation (SNP) | VAF 41/113 reads (36%) | catalogued as COSV100386423; called by muse, mutect2, varscan2
- ZNF585A | c.1664G>C p.C555S (on ENST00000292841 / NM_001288800.2; = p.C500S on NM_152655.3) | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99492995; called by muse, mutect2, varscan2
- ZNF626 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs267605381, COSV101656974; called by muse, mutect2, varscan2
- ZNF648 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV100374525; called by muse, mutect2, varscan2
- ZNF667 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV99410283; called by muse, mutect2, varscan2
- ZNF761 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100483351; called by muse, mutect2, varscan2
- ZNF763 | c.711T>A p.F237L (on ENST00000358987 / NM_001367172.2; = p.F240L on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV100676057; called by muse, mutect2, varscan2
- ZNF773 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs554581707, COSV56590716, COSV99989219; called by muse, mutect2, varscan2
- ZNF804A | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100167395; called by muse, mutect2, varscan2
- ZSCAN4 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100552462; called by muse, mutect2, varscan2
- AMPH | c.1503del p.E503Kfs*3 | Frame Shift Del (DEL) | VAF 35/149 reads (23%) | called by mutect2, pindel, varscan2
- AQP9 | c.755dup p.L252Ffs*16 | Frame Shift Ins (INS) | VAF 33/183 reads (18%) | called by mutect2, pindel, varscan2
- CLEC6A | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- GJA8 | c.629del p.L210Cfs*12 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | called by mutect2, pindel, varscan2
- GRM8 | c.321del p.R108Gfs*10 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- INTS7 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KIF5A | c.2181del p.I728Lfs*7 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- LNPEP | c.145del p.R49Gfs*34 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- LRRCC1 | c.154dup p.C52Lfs*3 | Frame Shift Ins (INS) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- MAGEB1 | c.635del p.G212Afs*13 | Frame Shift Del (DEL) | VAF 16/22 reads (73%) | called by mutect2, varscan2
- MRC1 | c.505_506insT p.A169Vfs*7 | Frame Shift Ins (INS) | VAF 38/182 reads (21%) | called by mutect2, pindel*
- MX2 | c.1574-6_1603delinsTGGTCAGAAATTATCCAGCAAGCTTTCATTAACGTT p.X525_splice | Splice Site (ONP) | VAF 6/47 reads (13%) | called by mutect2*, pindel, varscan2*
- OR5K3 | c.116dup p.M39Ifs*50 | Frame Shift Ins (INS) | VAF 83/307 reads (27%) | called by mutect2, pindel, varscan2
- PCDHGB3 | c.1180del p.I394Sfs*12 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- PIGF | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- PLXNA2 | c.5560_5564del p.Y1854Lfs*6 | Frame Shift Del (DEL) | VAF 45/120 reads (38%) | called by mutect2, pindel, varscan2
- SF1 | c.756del p.T253Pfs*10 | Frame Shift Del (DEL) | VAF 46/134 reads (34%) | called by mutect2, pindel, varscan2
- TMEM236 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- ZHX3 | c.1181dup p.L395Tfs*66 | Frame Shift Ins (INS) | VAF 32/107 reads (30%) | called by mutect2, pindel, varscan2
- ZNF658 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 71/181 reads (39%) | called by muse, mutect2, varscan2
- ABCC11 | c.2172G>A p.G724= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV100750694; called by muse, mutect2, varscan2
- ADAM32 | c.1860G>A p.K620= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV101165326; called by muse, mutect2, varscan2
- ADCY8 | c.3129G>T p.V1043= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV53901333; called by muse, mutect2, varscan2
- AHCTF1 | c.5715G>A p.R1905= (on ENST00000366508; = p.R1879= on NM_015446.5) | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV100403499; called by muse, mutect2, varscan2
- AL121899.2 | c.1947G>T p.L649= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV101198431; called by muse, mutect2, varscan2
- ARHGAP4 | c.864G>A p.T288= | Silent (SNP) | VAF 39/52 reads (75%) | catalogued as rs781843809, COSV100603995; called by muse, mutect2, varscan2
- ARID5B | c.153G>C p.P51= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV99689487; called by muse, mutect2, varscan2
- ASTN1 | c.45G>T p.G15= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99921212; called by muse, mutect2, varscan2
- BCL2L1 | c.447A>G p.A149= | Silent (SNP) | VAF 68/236 reads (29%) | catalogued as rs201719152, COSV56967605, COSV56969995; called by muse, mutect2, varscan2
- BNC1 | c.777A>G p.S259= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs138172246; called by muse, mutect2, varscan2
- BPNT2 | c.294G>C p.T98= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99388970; called by muse, mutect2, varscan2
- CACNA1E | c.2007C>G p.S669= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as COSV100702095; called by muse, mutect2, varscan2
- CCDC112 | c.966C>G p.T322= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV101100419; called by muse, mutect2, varscan2
- CCT5 | c.204G>T p.V68= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as COSV99725263; called by muse, mutect2
- CEP70 | c.933G>A p.K311= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99389072; called by muse, varscan2
- CHAT | c.1347C>T p.V449= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1055036701, COSV100340031; called by muse, mutect2
- CIT | c.3457C>T p.L1153= | Silent (SNP) | VAF 106/329 reads (32%) | catalogued as rs1287725973, COSV99949276; called by muse, mutect2, varscan2
- CLASRP | c.534G>A p.A178= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs778698410, COSV55515443; called by muse, mutect2, varscan2
- CNTN5 | c.939T>G p.A313= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99675624; called by muse, mutect2, varscan2
- CSMD3 | c.10578G>T p.G3526= (on ENST00000297405 / NM_001363185.1; = p.G3357= on NM_052900.3) | Silent (SNP) | VAF 38/145 reads (26%) | catalogued as COSV99831565; called by muse, mutect2, varscan2
- CSNK2A1 | c.606A>G p.L202= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs369232772; called by muse, mutect2, varscan2
- CYP26A1 | c.424C>A p.R142= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs765472185, COSV99814659; called by muse, mutect2, varscan2
- CYP3A4 | c.156C>T p.S52= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs754473590, COSV100315594, COSV100315933; called by muse, mutect2, varscan2
- DEFA5 | c.132C>A p.I44= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV100400448; called by muse, mutect2, varscan2
- DKK1 | c.150C>A p.G50= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100906526, COSV64760521; called by muse, mutect2, varscan2
- DKK2 | c.417C>A p.I139= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV53402951, COSV99568553; called by muse, mutect2, varscan2
- DMBT1 | c.2121G>T p.R707= | Silent (SNP) | VAF 45/329 reads (14%) | catalogued as COSV100352723; called by muse, mutect2, varscan2
- ENG | c.1014C>A p.P338= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100785247; called by muse, mutect2, varscan2
- FABP12 | c.234C>A p.G78= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV100846573; called by muse, mutect2, varscan2
- FAM135B | c.2154T>C p.V718= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99422493; called by muse, mutect2, varscan2
- FAM167A | c.82C>A p.R28= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV52702742, COSV99461421; called by muse, mutect2, varscan2
- FGFR4 | c.1675C>A p.R559= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs750069509, COSV99449571; called by muse, mutect2, varscan2
- FSIP2 | c.19419A>T p.T6473= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100554865; called by muse, mutect2, varscan2
- GASK1B | c.570C>A p.A190= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99647541; called by muse, mutect2, varscan2
- GLS | c.1917C>G p.L639= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs1487426982, COSV100289967; called by muse, mutect2, varscan2
- GRP | c.378C>A p.G126= | Silent (SNP) | VAF 88/155 reads (57%) | catalogued as COSV99900955; called by muse, mutect2, varscan2
- HCN1 | c.1371G>T p.L457= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs561869170, COSV57491077, COSV57497442, COSV57503513; called by muse, mutect2, varscan2
- HERC2 | c.13710G>A p.A4570= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs142882696; called by muse, mutect2
- KALRN | c.8622G>T p.L2874= (on ENST00000360013 / NM_001024660.4; = p.L1177= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99361759; called by muse, mutect2, varscan2
- KCNB2 | c.2446T>C p.L816= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV101578741; called by muse, mutect2, varscan2
- KCNV1 | c.1062C>A p.S354= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV99819029; called by muse, mutect2, varscan2
- KCTD10 | c.663G>C p.R221= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99949193; called by muse, mutect2, varscan2
- KDM2A | c.2937G>A p.L979= | Silent (SNP) | VAF 67/200 reads (34%) | catalogued as COSV100445511; called by muse, mutect2, varscan2
- KDR | c.945C>A p.T315= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV99817378; called by muse, mutect2, varscan2
- KLHL22 | c.459C>T p.L153= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as rs776470008, COSV100185949; called by muse, mutect2
- LALBA | c.309C>T p.D103= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as COSV99974385; called by muse, mutect2, varscan2
- LCE3B | c.69A>G p.P23= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as COSV100167511; called by muse, mutect2, varscan2
- LILRA2 | c.1068C>A p.T356= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs369982018, COSV99253205; called by muse, mutect2, varscan2
- MATN2 | c.531G>T p.V177= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99646113; called by muse, mutect2, varscan2
- MRGPRD | c.597G>C p.L199= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV58422757; called by muse, mutect2, varscan2
- MSC | c.43C>A p.R15= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100335655, COSV57697415; called by muse, mutect2, varscan2
- MUC2 | c.1872G>T p.V624= | Silent (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- MZT2B | c.366G>A p.A122= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs746156820, COSV99919776; called by muse, mutect2, varscan2
- N4BP2L2 | c.465A>G p.Q155= | Silent (SNP) | VAF 52/111 reads (47%) | catalogued as COSV99912506; called by muse, mutect2, varscan2
- NCDN | c.366C>A p.A122= | Silent (SNP) | VAF 34/207 reads (16%) | catalogued as COSV100357278; called by muse, mutect2, varscan2
- NLRP9 | c.1569A>T p.I523= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV100242947; called by muse, mutect2, varscan2
- NPAT | c.2661A>T p.V887= | Silent (SNP) | VAF 53/193 reads (27%) | catalogued as COSV99585952; called by muse, mutect2, varscan2
- NRAP | c.1026A>G p.K342= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100748390; called by muse, mutect2
- OR2A2 | c.468G>T p.L156= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as COSV101286643; called by muse, mutect2, varscan2
- OR8B12 | c.228C>A p.I76= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV100172738, COSV60911594, COSV60912162; called by muse, mutect2, varscan2
- PCDH10 | c.2679C>T p.R893= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99993390; called by muse, mutect2, varscan2
- PCDHA6 | c.2118G>A p.A706= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV100971406; called by muse, mutect2, varscan2
- PCDHB14 | c.2154G>A p.R718= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as rs1564002408, COSV99505778; called by muse, mutect2, varscan2
- PCDHB8 | c.1377G>T p.L459= | Silent (SNP) | VAF 33/188 reads (18%) | catalogued as COSV99176844; called by muse, mutect2, varscan2
- PI4KA | c.2466G>T p.G822= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as COSV99745602; called by muse, mutect2, varscan2
- PLCB4 | c.3495C>A p.A1165= (on ENST00000278655 / NM_182797.3; = p.R1178= on NM_000933.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99595144; called by muse, mutect2, varscan2
- POM121L12 | c.69G>T p.L23= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV101374901; called by muse, mutect2, varscan2
- PPP1R16A | c.813C>A p.A271= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV52952389, COSV99477545; called by muse, mutect2, varscan2
- PRDM9 | c.1086C>A p.G362= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV99690270; called by muse, mutect2, varscan2
- REXO1 | c.1002G>T p.L334= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV99402230; called by muse, mutect2
- RND1 | c.309A>T p.A103= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100552139; called by muse, mutect2, varscan2
- RTN4 | c.1410A>G p.A470= | Silent (SNP) | VAF 66/166 reads (40%) | catalogued as rs957627992, COSV100463027; called by muse, mutect2, varscan2
- RXFP2 | c.375A>C p.V125= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100034233; called by muse, mutect2, varscan2
- SCAPER | c.2982C>T p.Y994= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100238017; called by muse, mutect2, varscan2
- SDK1 | c.1311G>T p.V437= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV101269201; called by muse, mutect2, varscan2
- SKIV2L | c.2391G>A p.E797= | Silent (SNP) | VAF 44/78 reads (56%) | catalogued as COSV100514630; called by muse, mutect2, varscan2
- SLC18A3 | c.1140C>T p.F380= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV60319953; called by muse, mutect2, varscan2
- SORCS1 | c.3027G>A p.L1009= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1288252945, COSV53866340; called by muse, mutect2, varscan2
- SORCS3 | c.2676A>T p.T892= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100863520; called by muse, mutect2, varscan2
- SPEG | c.3576G>T p.R1192= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs773147309, COSV100404155; called by muse, mutect2, varscan2
- STX11 | c.711G>A p.K237= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as COSV62450739; called by muse, mutect2, varscan2
- SYNJ2 | c.1587G>T p.R529= | Silent (SNP) | VAF 47/76 reads (62%) | catalogued as COSV100840142; called by muse, mutect2, varscan2
- TBKBP1 | c.270G>C p.L90= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100659089; called by muse, mutect2, varscan2
- TENM2 | c.6574C>T p.L2192= (on ENST00000518659 / NM_001122679.2; = p.L1953= on NM_001080428.3) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV101318508; called by muse, mutect2, varscan2
- TEX15 | c.459T>C p.G153= (on ENST00000256246; = p.G536= on NM_001350162.2) | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as COSV99821197; called by muse, mutect2, varscan2
- TEX44 | c.60A>T p.P20= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100009704; called by muse, mutect2, varscan2
- TMCO3 | c.423C>T p.A141= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1386828038, COSV100952307; called by muse, mutect2, varscan2
- TMEM192 | c.12G>T p.G4= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100122078; called by muse, mutect2, varscan2
- TMUB1 | c.666C>T p.P222= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99879700; called by muse, mutect2, varscan2
- TRPM4 | c.672C>T p.P224= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99419570; called by muse, mutect2, varscan2
- UPK1B | c.39C>A p.G13= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV99953583; called by muse, mutect2, varscan2
- UPK3A | c.696C>A p.L232= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99343105; called by muse, mutect2, varscan2
- ZBTB7C | c.1125G>T p.G375= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV100134361; called by muse, mutect2, varscan2
- ZFPM2 | c.2524C>A p.R842= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs374720145, COSV101023173; called by muse, mutect2, varscan2
- ZKSCAN8 | c.279G>T p.L93= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV100362874; called by muse, mutect2, varscan2
- ZNF10 | c.672C>T p.H224= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99939940; called by muse, mutect2
- ZNF516 | c.2955A>T p.P985= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs750881976, COSV101487257; called by muse, mutect2
- CRTC3 | c.*2C>T | 3'UTR (SNP) | VAF 26/54 reads (48%) | catalogued as rs1275696480, COSV99185656; called by muse, mutect2, varscan2
- DST | c.4297-4005A>G | Intron (SNP) | VAF 22/132 reads (17%) | catalogued as COSV99754447; called by muse, mutect2, varscan2
- IGKV1-13 | n.334A>C | RNA (SNP) | VAF 31/255 reads (12%) | called by muse, mutect2, varscan2
- KCNH7 | c.2154+49A>T | Intron (SNP) | VAF 17/112 reads (15%) | catalogued as COSV100035329; called by muse, mutect2, varscan2
- LINC02872 | n.220G>A | RNA (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- MIR154 | n.65G>T | RNA (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- OR8A1 | c.-13C>G | 5'UTR (SNP) | VAF 20/61 reads (33%) | catalogued as COSV52508573, COSV99420517; called by muse, mutect2, varscan2
- SPATA8 | n.245G>T | RNA (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100138933; called by muse, mutect2, varscan2
- TPK1 | c.185+15152G>T | Intron (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100765586, COSV63639637; called by muse, mutect2, varscan2
- ZNF208 | c.*467A>T | 3'UTR (SNP) | VAF 10/31 reads (32%) | catalogued as COSV68101033; called by muse, mutect2, varscan2
